Somatic mutation profile of tumor specimen TCGA-DM-A0XF-01A (aliquot TCGA-DM-A0XF-01A-11D-A152-10) from TCGA case TCGA-DM-A0XF, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.5 years (25,032 days).
Specimen TCGA-DM-A0XF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea5c481a-3748-45d6-9fbc-dbc09a00d56b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A0XF-10A (Blood Derived Normal), aliquot TCGA-DM-A0XF-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dab21eb6-4073-4a50-8040-af0b6d2a32ce

The open-access MAF lists 136 somatic variants for this specimen: 100 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 32, Nonsense Mutation 7, Frame Shift Del 3, Intron 2, RNA 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 44/162 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, varscan2
- ABI3BP | c.1441A>G p.S481G | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.146); catalogued as COSV52529186; called by muse, mutect2, varscan2
- ADAM15 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV55128098; called by muse, mutect2, varscan2
- AGO1 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64594734; called by muse, mutect2, varscan2
- AHNAK | c.12439G>A p.V4147M | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs201311159, COSV57203760; called by muse, mutect2, varscan2
- ALG11 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73000573; called by muse, mutect2, varscan2
- ALG8 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs140716983; called by muse, mutect2, varscan2
- APC | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 33/92 reads (36%) | catalogued as CD011096, COSV57327136; called by muse, mutect2, varscan2
- ARHGAP25 | c.251C>T p.T84M (on ENST00000409202 / NM_001007231.3; = p.T77M on NM_014882.3) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs778446861, COSV54898813; called by muse, mutect2, varscan2
- ATRNL1 | c.3289T>A p.Y1097N | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100372648; called by muse, mutect2
- AXDND1 | c.1152A>T p.E384D | Missense Mutation (SNP) | VAF 45/411 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.237); catalogued as COSV62640015; called by muse, mutect2, varscan2
- B4GALNT3 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756076751, COSV56750072, COSV99842427; called by muse, mutect2, varscan2
- BCHE | c.1459G>T p.A487S | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV52253954; called by muse, mutect2, varscan2
- BRINP3 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1354388065, COSV66514554; called by muse, mutect2, varscan2
- CADPS | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs573592664, COSV51868558; called by muse, mutect2, varscan2
- CATIP | c.635A>T p.N212I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV56822150; called by muse, mutect2, varscan2
- CD22 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV50049744; called by muse, mutect2, varscan2
- CD48 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs146912720; called by muse, mutect2, varscan2
- CENPBD1 | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV51918003; called by muse, mutect2, varscan2
- CHAT | c.1974C>A p.S658R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60320605; called by muse, mutect2, varscan2
- CHD1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV52337566; called by muse, mutect2, varscan2
- CHD7 | c.7894A>C p.N2632H | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71107426; called by muse, mutect2, varscan2
- CLSTN1 | c.1384G>C p.V462L (on ENST00000377298 / NM_001009566.3; = p.V452L on NM_014944.4) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV63646301, COSV63646774; called by mutect2, varscan2
- CMYA5 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV71404194, COSV71408305; called by muse, mutect2, varscan2
- CNOT11 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV56819078; called by muse, mutect2
- CYP4A22 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs767886913, COSV53738388; called by muse, mutect2, varscan2
- CYP4Z1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs571972072, COSV61963888; called by muse, mutect2, varscan2
- DCHS1 | c.9187C>G p.R3063G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100197723; called by mutect2, varscan2
- DHX30 | c.2756C>A p.A919E (on ENST00000445061 / NM_138615.3; = p.A880E on NM_014966.3) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as COSV53135603; called by muse, mutect2, varscan2
- DISP1 | c.3049G>A p.A1017T | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV99452122; called by muse, mutect2
- DPYD | c.819A>C p.E273D | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64591621; called by muse, mutect2, varscan2
- DUOX1 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV100368434; called by muse, mutect2, varscan2
- EEF1A1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV58548609, COSV58550358; called by muse, mutect2, varscan2
- EPRS1 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs149264109; called by muse, mutect2, varscan2
- ESRRA | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV50004731; called by muse, mutect2
- FBXL5 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58009847; called by muse, mutect2, varscan2
- FLNC | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777692031, COSV57950740; called by muse, mutect2, varscan2
- GOLGB1 | c.3850T>A p.L1284M | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.919); catalogued as COSV100511480; called by muse, mutect2, varscan2
- HEATR4 | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100408115; called by muse, mutect2, varscan2
- ICAM4 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV99321120; called by muse, mutect2
- IL1RAPL2 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375566296, COSV100781898; called by muse, mutect2, varscan2
- IQSEC3 | c.2468C>T p.P823L (on ENST00000538872 / NM_001170738.2; = p.P520L on NM_015232.1) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV58281057; called by muse, mutect2, varscan2
- JAKMIP2 | c.193A>T p.K65* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV99509177; called by muse, mutect2, varscan2
- KCNB2 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049061; called by muse, varscan2
- KRTAP23-1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 10/122 reads (8%) | PolyPhen possibly damaging (0.574); catalogued as COSV100492619, COSV61935530; called by muse, mutect2
- LAMB4 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 17/169 reads (10%) | catalogued as COSV52713973; called by muse, mutect2, varscan2
- LIPE | c.2375C>T p.T792M | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as rs942487236, COSV54921516; called by muse, mutect2, varscan2
- LPA | c.4675C>A p.Q1559K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV60297588; called by muse, mutect2, varscan2
- MAGEB2 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV66780228, COSV66781776; called by muse, mutect2, varscan2
- MAGEC1 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); catalogued as COSV53568613; called by muse, mutect2, varscan2
- MCEE | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54905303; called by muse, mutect2, varscan2
- MEFV | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1167470161, COSV99561231; called by muse, mutect2
- MGAM | c.3368C>A p.S1123Y | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72073742, COSV72074764; called by muse, mutect2, varscan2
- MS4A10 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.429); catalogued as COSV100382416; called by muse, mutect2, varscan2
- MS4A14 | c.1966T>C p.F656L | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs747204523, COSV55733345; called by muse, mutect2, varscan2
- MUC20 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 96/350 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.225); catalogued as COSV57847888; called by muse, mutect2, varscan2
- NALCN | c.308T>A p.V103E | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV51919962; called by muse, mutect2, varscan2
- NPAS4 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749883401, COSV60649002; called by mutect2, varscan2
- NUP42 | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV51728795; called by muse, mutect2, varscan2
- OR10T2 | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100555103; called by muse, mutect2, varscan2
- OR2M4 | c.129T>G p.I43M | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV60707333; called by muse, mutect2, varscan2
- PAX7 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64748691; called by muse, mutect2, varscan2
- PAX7 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV100946958; called by muse, mutect2, varscan2
- PBDC1 | c.475T>C p.Y159H | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV64895604; called by muse, mutect2
- PCDH18 | c.1027A>C p.K343Q | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100787499; called by muse, mutect2, varscan2
- PCDHB6 | c.793G>C p.A265P | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50690466; called by muse, mutect2, varscan2
- PDE4D | c.2068G>T p.V690F (on ENST00000340635 / NM_001104631.2; = p.V554F on NM_006203.4) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100401815, COSV57715130; called by muse, mutect2, varscan2
- PHF8 | c.1841C>T p.T614M (on ENST00000357988 / NM_001184896.1; = p.T578M on NM_015107.3) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.116); catalogued as rs373224451, COSV57677775; called by muse, mutect2, varscan2
- POU2F1 | c.1366A>G p.S456G (on ENST00000541643 / NM_001365848.1; = p.S479G on NM_002697.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99612067; called by muse, mutect2, varscan2
- PPP4R1 | c.843T>A p.C281* (on ENST00000400556 / NM_001042388.3; = p.C264* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/184 reads (15%) | catalogued as COSV53280561; called by muse, mutect2, varscan2
- PSG3 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59502644; called by muse, mutect2, varscan2
- RALGPS1 | c.1499T>C p.L500P | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV52216506; called by muse, mutect2, varscan2
- RESF1 | c.4331T>A p.L1444Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV57019903; called by muse, mutect2, varscan2
- RRP9 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51753071; called by muse, mutect2, varscan2
- SEMA3A | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs143007146, CM130574; called by muse, mutect2, varscan2
- SEMA6B | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as rs777813030, COSV56702463; called by mutect2, varscan2
- SIMC1 | c.494C>A p.S165Y (on ENST00000443967 / NM_001308196.1; = p.S184Y on NM_001308195.2) | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57900434; called by muse, mutect2, varscan2
- SLC25A12 | c.1172G>C p.G391A | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV99785387; called by muse, mutect2, varscan2
- SMG1 | c.6245C>T p.A2082V | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV67169663; called by muse, mutect2, varscan2
- SPTB | c.3744G>C p.K1248N | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67629998; called by muse, mutect2, varscan2
- SYNE1 | c.706C>T p.R236* (on ENST00000367255 / NM_182961.4; = p.R243* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV54899826; called by muse, mutect2, varscan2
- TMPRSS6 | c.860A>T p.E287V | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60975247; called by muse, mutect2, varscan2
- TSHR | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.249); catalogued as COSV53314914; called by muse, mutect2, varscan2
- TTN | c.80825C>A p.S26942Y (on ENST00000591111; = p.S19518Y on NM_003319.4) | Missense Mutation (SNP) | VAF 45/293 reads (15%) | PolyPhen possibly damaging (0.804); catalogued as COSV59904756; called by muse, mutect2, varscan2
- TTN | c.17046C>A p.H5682Q (on ENST00000591111; = p.H4755Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/146 reads (20%) | PolyPhen benign (0.053); catalogued as COSV100628042; called by muse, mutect2, varscan2
- UBR5 | c.7432C>T p.R2478* | Nonsense Mutation (SNP) | VAF 17/170 reads (10%) | catalogued as COSV55280829; called by muse, mutect2, varscan2
- UBTF | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100256118; called by muse, mutect2
- WWP1 | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.625); catalogued as COSV55356690; called by muse, mutect2, varscan2
- ZC3H13 | c.3335del p.A1112Vfs*54 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as COSV54448236, COSV54457220; called by mutect2, pindel, varscan2
- ZDBF2 | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV65622404; called by muse, mutect2, varscan2
- ZNF404 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV100182829; called by muse, mutect2
- ZNF600 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs566585069, COSV57741472; called by muse, mutect2, varscan2
- ZNF835 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV101606398; called by muse, mutect2
- ARID1A | c.6730dup p.V2244Gfs*34 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- AXDND1 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.282); called by muse, mutect2
- DPYSL5 | c.1289_1298del p.M430Tfs*32 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel
- KIF4A | c.3668del p.G1223Afs*37 | Frame Shift Del (DEL) | VAF 31/176 reads (18%) | called by mutect2, pindel, varscan2
- RAP2B | c.552_*22del | Nonstop Mutation (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- TAL1 | c.555A>T p.K185N | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ANKRD11 | c.549C>T p.R183= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99970467; called by muse, mutect2
- ARMCX5 | c.1281C>T p.H427= | Silent (SNP) | VAF 41/264 reads (16%) | catalogued as COSV55765995; called by muse, mutect2, varscan2
- CAMK2G | c.1122T>C p.A374= (on ENST00000423381 / NM_001367518.1; = p.A340= on NM_001222.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV59480161; called by muse, mutect2, varscan2
- CDON | c.621C>A p.G207= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV54995397; called by muse, mutect2, varscan2
- CHD7 | c.1068C>T p.N356= | Silent (SNP) | VAF 21/207 reads (10%) | catalogued as rs1271318068, COSV71107423; called by muse, mutect2, varscan2
- DMBT1 | c.5265C>T p.N1755= (on ENST00000338354 / NM_001377530.1; = p.N998= on NM_004406.3) | Silent (SNP) | VAF 56/268 reads (21%) | catalogued as COSV57535563; called by muse, mutect2, varscan2
- DUOX1 | c.489G>T p.R163= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100368433; called by muse, mutect2
- EBI3 | c.177C>T p.P59= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs748030368, COSV55689585; called by muse, mutect2, varscan2
- ESX1 | c.1191C>A p.I397= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV65423950; called by muse, mutect2, varscan2
- EYA4 | c.306C>A p.P102= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV62046347; called by muse, mutect2, varscan2
- FLNC | c.8148T>A p.P2716= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV50799967; called by muse, mutect2, varscan2
- FUBP1 | c.549G>A p.P183= | Silent (SNP) | VAF 50/89 reads (56%) | catalogued as rs758508471, COSV53926847, COSV53933570; called by muse, mutect2, varscan2
- FZD10 | c.87G>T p.P29= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs747697911, COSV57472321, COSV99969452; called by muse, mutect2, varscan2
- HIPK3 | c.3102T>A p.P1034= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV57561025; called by muse, mutect2, varscan2
- HUWE1 | c.11784T>G p.P3928= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV99474071; called by muse, mutect2, varscan2
- IQGAP1 | c.2244G>T p.L748= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV51581729, COSV51581873; called by muse, mutect2, varscan2
- KIF2B | c.351G>A p.A117= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs758387314, COSV52127365; called by muse, mutect2, varscan2
- KMT2D | c.3774G>C p.R1258= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV56414002; called by muse, mutect2, varscan2
- MDC1 | c.5568C>T p.V1856= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs745466962, COSV64523431; called by muse, mutect2, varscan2
- MICAL1 | c.108C>A p.A36= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV62192114; called by muse, mutect2, varscan2
- NKX2-4 | c.645G>C p.S215= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100698627; called by muse, mutect2, varscan2
- OR1C1 | c.936G>A p.Q312= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV68715410; called by muse, mutect2, varscan2
- OSBPL3 | c.2643G>T p.L881= | Silent (SNP) | VAF 32/312 reads (10%) | catalogued as COSV100514487; called by muse, mutect2
- PADI1 | c.648C>T p.A216= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV64937823; called by muse, mutect2
- PDCD1 | c.537C>T p.G179= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs932644449, COSV57690719; called by muse, mutect2, varscan2
- PRKCD | c.132G>A p.L44= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV57848004; called by muse, mutect2, varscan2
- TMEM164 | c.81C>T p.P27= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV55810740; called by muse, mutect2, varscan2
- UBA3 | c.969G>T p.V323= | Silent (SNP) | VAF 17/350 reads (5%) | catalogued as COSV100734766; called by muse, mutect2
- XRRA1 | c.1731C>A p.I577= | Silent (SNP) | VAF 21/162 reads (13%) | catalogued as COSV55130684; called by muse, mutect2, varscan2
- ZBTB39 | c.606G>A p.P202= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs758837743, COSV55627688; called by muse, mutect2, varscan2
- ZCCHC12 | c.834C>T p.I278= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs1055792408, COSV59570972; called by muse, mutect2, varscan2
- ZNF513 | c.222G>A p.L74= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99277918; called by muse, mutect2, varscan2
- CACNA1D | c.1478+339G>T | Intron (SNP) | VAF 13/84 reads (15%) | catalogued as COSV55438601; called by muse, mutect2, varscan2
- LAMP2 | c.1093+2487G>T | Intron (SNP) | VAF 79/259 reads (31%) | catalogued as COSV52351603; called by muse, mutect2, varscan2
- MIR299 | n.16G>A | RNA (SNP) | VAF 11/25 reads (44%) | catalogued as rs374292470; called by muse, mutect2
- MIR30A | n.41G>A | RNA (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
